Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A931, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A931-01A (Primary Tumor).

[page 1 of 2]
Patient Name

MRN:

DOB:

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: THYMOMA

ICD-O-3
Thymoma, type B3, malignant
8585/3
Site Thymus C37.9
QW4/2/14

DIAGNOSIS

1. Thymus, resection (thymoma):

a) Thymoma, WHO type B3 (see Comment), with:

i) Greatest tumor dimension = 3.7 cm

ii) Multifocal microscopic invasion into mediastinal fat present

iii) Painted resection margins negative for tumor

b) Thymic tissue with involutional changes

c) One parathyroid gland without significant abnormality

SYNOPTIC DATA

Specimen Type:	Not specified
Tumor Site:	Thymus
Tumor Size:	Greatest dimension: 3.7 cm
Histologic Type:	Type B thymoma, B3 (epithelial, atypical, squamoid, well-differentiated thymic carcinoma)
Pathologic Staging:	Stage IIa: Microscopic transcapsular invasion
Regional Lymph Nodes:	pNX: Cannot be assessed
Distant Metastasis:	Cannot be assessed
Margins:	Margins uninvolved by tumor

COMMENT

Sections show an encapsulated tumor composed of nests of cells separated by thick fibrous septae. Several areas of microscopic transcapsular invasion into the surrounding fat are noted, but the painted margins of

[page 2 of 2]
Department of Pathology

Patient Name:

MRN:

DOB:

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

resection appear free of tumor. The majority of the tumor cells are polygonal, with mildly atypical nuclei containing single nucleoli. The tumor is predominantly epithelial, with only occasional interspersed small lymphocytes present in most of the tumor (WHO B3 pattern). However, a few areas of increased numbers of lymphocytes are noted (WHO B2 pattern). The tumor cells stain positive for high and low molecular weight keratins, CK 5/6 and p63 by immunohistochemistry. Rare small lymphocytes stain positive for CD1a through most of the tumor, with more CD1a lymphocytes present in some areas.

Overall, the findings are in keeping with thymoma, WHO B3 type (aka epithelial thymoma, well-differentiated thymic carcinoma), with microscopic invasion of surrounding fat (modified Masaoka stage IIa).

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

MYASTHENIA GRAVIS

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "thymus: Thymoma".

One irregular piece of adipose tissue, with overall measurements of 15.5 x 7.5 x 1.7 cm, which weighs 32.2 g and is painted with silver nitrate

Tumor: Relatively well circumscribed, measuring 3.7 x 1.1 x 2.5 cm, with a tan, irregular, soft parenchyma.

Tissue banking: The tumor and normal tissue are sampled for tissue banking.

Representative sections are submitted as follows:

1A-1D tumor

1E-1J adipose tissue

Status: supplemental

Source: NCI Genomic Data Commons file 3f00ff52-8574-425f-8bcb-2100e2bd4b30 (TCGA-XU-A931.B64C96CE-2E34-4ADD-9FF1-1BF5C0A7190A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).